Surgical pathology report (de-identified scan), TCGA case TCGA-HC-A6HY, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-A6HY-01A (Primary Tumor).

[page 1 of 2]
Accession # [REDACTED] Hospital #
Hospital ID:
DOE Age/Sex M
Attending Physician
Ordering Physician:
Performing Physician:
Collection Date:
Hospital of Origin:
Copy to:

QC Pathologist:

FINAL PATHOLOGIC DIAGNOSIS:

Prostate, radical prostatectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Prostate size: 4.8 x 4.1 x 3.4 cm, 52 grams.
3. Tumor quantitation: Tumor involves approximately half of the prostate and both lobes.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 7/10.
5. Extraprostatic extension: No.
6. Seminal vesicle involvement: No.
7. Lymphovascular space invasion: No.
8. High grade PIN: Yes.
9. Treatment effect: N/A.
- Surgical Margin Status:
1. Margins are negative for tumor involvement.
- Lymph Node Status:
1. Total number of lymph nodes received: 0.
- Other:
1. pTNM stage: pT2c.

COMMENTS:

CLINICAL HISTORY:

Preoperative Diagnosis: No clinical.

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

Prostate right blue, left black.

CODES:

88309

PROCEDURAL DEMOGRAPHICS:

Date of Procedure:

Accession Date/Time:

ICD-O-3

Adenocarcinoma, acinar
8140/3

Adenocarcinoma NOS
8140/3

Site: Prostate NOS
C61.9

6/12/13

[page 2 of 2]
GROSS DESCRIPTION:

Received in formalin labeled _____ and prostate is a 52 gram previously inked and sampled radical prostatectomy specimen received for research, 4.8 x 4.1 x 3.4 cm. The right side is inked black and the left side blue. The right posterior aspect at the mid level has been previously sampled for research. There is a bulging fibrotic nodule on the right lateral aspect measuring 1.4 cm. in greatest dimension. The right posterior aspect displays a 0.6 cm. poorly defined pale yellow area of discoloration involving the mid and proximal levels. It is 0.2 cm. from the right posterior margin. Additional abnormalities are not identified.

The seminal vesicals together measure 5.2 x 2.0 x 0.6 cm. Each has a cystic cut surface and is uninvolved by lesion. Representative sections are submitted as follows: 1 and 2--apical margin; 3--vesical margin; 4--distal left lateral; 5--distal right lateral; 6--distal right posterior; 7--distal left posterior; 8--mid left lateral; 9--mid right lateral; 10--mid right posterior; 11--mid left posterior; 12--proximal left lateral; 13--proximal right lateral; 14--proximal right posterior; 15--proximal left posterior; 16--origin of seminal vesicles; 17--representative left seminal vesicle; 18--representative right seminal vesicle.

Urethral Discrepancy		✓
UAPAX Discrepancy		✓
Proximal Discrepancy History		✓

Source: NCI Genomic Data Commons file 15d355b5-da75-455c-b799-8835d0118e97 (TCGA-HC-A6HY.91DC18E8-EF04-47C0-A77F-632A9DE2BA55.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).